CCDI case PBBLNU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Spinal cord, cranial nerves, and other parts of central nervous system.
https://portal.gdc.cancer.gov/cases/803671c3-6dfc-4dea-a467-cb2a5e3f7a73

Demographics
Sex at birth: female.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Spinal cord; Age at diagnosis: 8.2 years (3,007 days).

Biospecimens (3 samples)
- Sample 0DBQF5: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DBQF9: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DBQFD: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
